Somatic mutation profile of tumor specimen TARGET-30-PAPVFD-01A (aliquot TARGET-30-PAPVFD-01A-01D) from TARGET case TARGET-30-PAPVFD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 5.4 years (1,961 days).
Specimen TARGET-30-PAPVFD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3e64cca-451e-4eea-814c-0c267b8fbfbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPVFD-10A (Blood Derived Normal), aliquot TARGET-30-PAPVFD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a244ff29-5564-4220-98ab-880749a0f365

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C7 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV57471355; called by muse, mutect2, varscan2
- CFHR5 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV56818393; called by muse, mutect2, varscan2
- CLCA4 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV55366552; called by muse, mutect2, varscan2
- CTNNA3 | c.1161C>A p.D387E | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65556155; called by muse, mutect2, varscan2
- DRC1 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56529272; called by muse, mutect2, varscan2
- HCFC2 | c.988T>C p.W330R | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558029; called by muse, mutect2, varscan2
- HERC2 | c.13567G>C p.A4523P | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.727); catalogued as COSV55309551; called by muse, mutect2, varscan2
- HOXB6 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV53312156; called by muse, mutect2
- INPPL1 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762627344, COSV53353501; called by muse, mutect2, varscan2
- KLHDC7B | c.1729C>T p.L577F (on ENST00000395676; = p.L1218F on NM_138433.5) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755778420, COSV67464247; called by muse, mutect2, varscan2
- MECOM | c.1124G>A p.R375K (on ENST00000468789 / NM_001105078.4; = p.R563K on NM_004991.4) | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV52960219; called by muse, mutect2, varscan2
- NETO1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV55002252; called by muse, mutect2, varscan2
- PPA2 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58993550; called by muse, mutect2, varscan2
- SLC12A7 | c.3076G>A p.V1026I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs755398930, COSV53754819; called by muse, mutect2, varscan2
- ST18 | c.2947G>T p.A983S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV52485501, COSV52489718; called by muse, mutect2, varscan2
- STAM2 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs761906826, COSV55729828; called by muse, mutect2, varscan2
- TGFA | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV54912116; called by muse, mutect2, varscan2
- ZDHHC17 | c.1823C>G p.P608R | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58350403; called by muse, mutect2, varscan2
- ACBD4 | c.612A>C p.G204= (on ENST00000376955 / NM_001378111.1; = p.N208H on NM_024722.4) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV58850860; called by muse, mutect2, varscan2
- DOCK9 | c.1518G>A p.V506= (on ENST00000376460 / NM_001366676.2; = p.V507= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV59621052; called by muse, mutect2, varscan2
- POM121L12 | c.657C>A p.P219= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs766549462, COSV68692305; called by muse, mutect2, varscan2
- PPP2R5E | c.726G>T p.L242= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV61740678; called by muse, mutect2, varscan2
- STAMBP | c.1083G>A p.E361= | Silent (SNP) | VAF 248/558 reads (44%) | catalogued as COSV100277675, COSV59896937; called by muse, mutect2, varscan2
